CCDI case PBBNMN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/161eac11-c35a-42ba-9ff9-43310e8ec3ba

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Malignant tumor, spindle cell type: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 6.0 years (2,186 days).

Biospecimens (3 samples)
- Sample 0DDA73: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDA7E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFSQO: Tissue type: Tumor; Specimen type: Solid Tissue.
